Somatic mutation profile of tumor specimen TCGA-AR-A0U0-01A (aliquot TCGA-AR-A0U0-01A-11D-A10G-09) from TCGA case TCGA-AR-A0U0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.9 years (26,993 days).
Specimen TCGA-AR-A0U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfb84f98-ebdd-4699-9533-6d88f6f738d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0U0-10A (Blood Derived Normal), aliquot TCGA-AR-A0U0-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a115052c-7cbd-4df6-a4d2-8e1ba9813b89

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1700_1711del p.K567_L570del (on ENST00000521381 / NM_181523.3; = p.K297_L300del on NM_181504.4) | In Frame Del (DEL) | VAF 16/81 reads (20%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 46/104 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.3388C>G p.Q1130E | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100662071; called by muse, mutect2
- ATP12A | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV54518622; called by muse, mutect2, varscan2
- BTG3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100336247; called by muse, mutect2, varscan2
- C3orf70 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV58588803; called by muse, mutect2, varscan2
- CCDC178 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV55781252; called by muse, mutect2, varscan2
- CILK1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV63154886; called by muse, mutect2, varscan2
- COL17A1 | c.4426A>C p.K1476Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV59826559; called by muse, mutect2, varscan2
- DNAH8 | c.5866C>T p.R1956C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773222614, COSV59452518; called by muse, mutect2, varscan2
- EHHADH | c.2024T>C p.V675A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV51631242; called by muse, mutect2, varscan2
- ELL3 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs935965442, COSV100082497; called by muse, mutect2
- FDXACB1 | c.1551T>A p.N517K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99499582; called by muse, mutect2, varscan2
- FNIP1 | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV57197779; called by muse, mutect2, varscan2
- FXR1 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs755691527, COSV59764077; called by muse, mutect2, varscan2
- KIAA1586 | c.1992T>A p.Y664* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100875307; called by muse, mutect2
- KMT2C | c.2930G>A p.C977Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100070596, COSV51457712; called by muse, mutect2, varscan2
- LONRF2 | c.1604C>A p.T535N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV66541218; called by mutect2, varscan2
- MYCT1 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.165); catalogued as COSV65891558; called by muse, mutect2, varscan2
- NFIC | c.1234C>G p.L412V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100545120; called by muse, mutect2
- OR2AK2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs113103144; called by muse, mutect2, varscan2
- PADI4 | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64924294; called by muse, mutect2, varscan2
- PKD2L1 | c.2198C>G p.S733* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58396839; called by muse, mutect2, varscan2
- SELL | c.53G>A p.W18* (on ENST00000650983; = p.W5* on NM_000655.5) | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as rs1243047313, COSV52552830; called by muse, mutect2, varscan2
- TTN | c.2429G>A p.R810H (on ENST00000591111; = p.R764H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | PolyPhen benign (0.019); catalogued as rs773966832, COSV60046828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS35L | c.1908G>C p.L636F | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51985674; called by muse, mutect2, varscan2
- WNT9B | c.689C>G p.P230R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs765555952, COSV99255014; called by muse, mutect2
- ZNF200 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1350412509, COSV67724018; called by muse, mutect2, varscan2
- ARID2 | c.3954dup p.C1319Vfs*6 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- CUL3 | c.1358dup p.N453Kfs*5 | Frame Shift Ins (INS) | VAF 40/146 reads (27%) | called by mutect2, varscan2
- BCL11B | c.2436G>A p.T812= (on ENST00000357195 / NM_001282237.2; = p.T741= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs756365436, COSV61735013; called by muse, mutect2
- DOCK10 | c.2790C>G p.T930= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV51419456, COSV99291493; called by mutect2, varscan2
- DSPP | c.2268C>T p.S756= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs770005489, COSV56812282; called by mutect2, varscan2
- EMILIN2 | c.1179G>A p.Q393= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1180648854, COSV54425018; called by muse, mutect2, varscan2
- IFI16 | c.306G>A p.V102= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99857178; called by muse, mutect2, varscan2
- RHBDD1 | c.513G>T p.P171= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as COSV58125794, COSV58128471; called by muse, mutect2, varscan2
- ZNF28 | c.702G>A p.Q234= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs1451229779, COSV60423884; called by muse, mutect2, varscan2
